Gene-level copy-number profile of tumor specimen TCGA-24-1847-01A from TCGA case TCGA-24-1847, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.3 years (16,529 days).
Specimen TCGA-24-1847-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4302237f-ebcb-49bb-93e0-17c4130b47c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1847-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb8f5f2c-fcd9-46d8-b11f-b3d4732ee3e9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,004; copy number 2: 18,993; copy number 3: 21,397; copy number 4: 12,484; copy number 5: 2,390; copy number 6: 1,338; copy number 7: 1,712; copy number 8: 496.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1847-01A-01D-0559-01): tumor purity 0.54, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,208 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:147,939,905–198,222,513, 906 genes, copy number 7 (broad region; genes not listed).
- chr8:68,695,643–96,336,995, 426 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:116,938,207–145,066,685, 496 genes, copy number 8 (broad region; genes not listed).
- chr11:117,986,370–132,404,060, 377 genes, copy number 7 (broad region; genes not listed).
- chr11:132,525,809–132,860,077, 3 genes, copy number 7: U6, AP003784.1, OPCML-IT2.

Autosomal genes at a single copy (total copy number 1): 1,004. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
